Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A3LW, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A3LW-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]

Physician: [REDACTED]

CC: [REDACTED]

Patient Address: [REDACTED]

Date of Receipt: [REDACTED]

Date of Report: [REDACTED]

....

Clinical Diagnosis & History:

Specimens Submitted:

1: SP: Retroperitoneal sarcoma and sigmoid colon

DIAGNOSIS:

- 1) SOFT TISSUE, RETROPERITONEUM, SIGMOID COLON; EXCISION:
- DEDIFFERENTIATED LIPOSARCOMA.
- THE TUMOR MEASURES 17 CM IN GREATEST DIMENSION.
- AREAS OF WELL-DIFFERENTIATED LIPOSARCOMA, SCLEROSING TYPE ARE ALSO PRESENT.
- THE TUMOR INVOLVES THE RETROPERITONEAL FAT AND THE PERICOLIC FAT.
- THE ESTIMATED AREAS OF NECROSIS ARE 20%.
- THE TUMOR FOCALLY EXTENDS TO THE INKED MARGINS.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

- 1) The specimen is received fresh, labeled "Retroperitoneal Sarcoma and Sigmoid Colon". It consists of a well-demarcated, encapsulated, rubbery tumor measuring 17 x 15 x 15 cm. On the lateral side there is an attached segment of sigmoid colon, measuring 30 cm in length. The surgical margins are stapled. The proximal margin measures 2.5 cm in circumference, the distal margin measures 2.8 cm in circumference. The serosa is smooth and shiny. The sigmoid mucosa grossly is unremarkable. The anterior surface of the tumor is partially covered by peritoneum. The mucosa is smooth, shiny and unremarkable. On the posterior side the surgical margin is inked. Cut sections of the tumor reveal a yellow-gray appearance with central areas of

** Continued on next page **

1CB-0-3
dedifferentiated liposarcoma 8858/3
Site: Retroperitoneum C48.0
hw 12/23/11

[page 2 of 2]
SURGICAL

Date of Report:

Page 2 of 2

necrosis and scattered hemorrhages. Twenty percent of the tumor is necrotic. Photographs are taken. The specimen is submitted for TPS.

Summary of Sections:

PBM proximal bowel margin

DBM distal bowel margin

S sigmoid

T tumor

TM tumor on the surgical margin

Summary of Sections:

Part 1: SP: Retroperitoneal sarcoma and sigmoid colon

Block	Sect. Site	PCs
1	dbm	1
1	pbm	1
2	s	2
10	t	10
4	tm	4

** End of Report **

Source: NCI Genomic Data Commons file 376165fe-76f0-40f9-ad1b-4a19b59c6a12 (TCGA-DX-A3LW.5B02C3F3-67DC-4694-A25E-39786BD38432.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).